Somatic mutation profile of tumor specimen TCGA-93-8067-01D (aliquot TCGA-93-8067-01D-01D-A38P-08) from TCGA case TCGA-93-8067, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 77.9 years (28,453 days).
Specimen TCGA-93-8067-01D: Sample type: FFPE Scrolls; Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8ac0b413-d138-4acf-b5aa-cbba131cde2c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-93-8067-10A (Blood Derived Normal), aliquot TCGA-93-8067-10A-01D-2284-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f3eb5735-f240-4024-ba48-9036aa5049b3

The open-access MAF lists 193 somatic variants for this specimen: 142 protein-altering or splice-affecting, 50 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 122, Silent 50, Nonsense Mutation 12, Frame Shift Del 4, Splice Site 4, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GCK | c.824G>T p.R275L | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.318); catalogued as rs767565869, COSV100357249, COSV60787127; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 16/70 reads (23%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- NFE2L2 | c.70T>C p.W24R | Missense Mutation (SNP) | VAF 7/35 reads (20%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1328994103, COSV67960091, COSV67960815, COSV67963035; called by muse, mutect2, varscan2
- ACER2 | c.654C>G p.I218M | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); catalogued as COSV100575821, COSV100575892; called by muse, mutect2, varscan2
- ADAM22 | c.2158G>C p.D720H | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT tolerated (0.21); PolyPhen benign (0.14); catalogued as COSV99717188; called by muse, mutect2
- ADCY5 | c.1401C>A p.N467K | Missense Mutation (SNP) | VAF 18/184 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.888); catalogued as COSV100567820, COSV59194839; called by muse, mutect2, varscan2
- ADCYAP1R1 | c.554G>A p.R185H | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs745856523, COSV58443114; called by mutect2, varscan2
- ALMS1 | c.3769C>T p.H1257Y | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT tolerated (0.17); PolyPhen benign (0.056); catalogued as COSV100042679; called by muse, mutect2, varscan2
- ANKMY1 | c.170G>A p.R57Q | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.886); catalogued as rs768966375, COSV56030766; called by mutect2, varscan2
- ANO6 | c.1639G>A p.E547K | Missense Mutation (SNP) | VAF 11/108 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100263347; called by muse, mutect2, varscan2
- ARHGAP6 | c.1088C>T p.S363L | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV100272988; called by muse, mutect2, varscan2
- ARHGEF18 | c.591G>C p.K197N (on ENST00000359920 / NM_001130955.2; = p.K93N on NM_015318.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/124 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.097); catalogued as COSV100149595; called by muse, mutect2
- ATXN7L1 | c.321G>C p.Q107H | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.24); catalogued as COSV100596886; called by muse, mutect2, varscan2
- BCAN | c.2183C>A p.T728K | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV100228173; called by muse, mutect2, varscan2
- BPTF | c.3451G>C p.E1151Q | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.383); catalogued as COSV100075117; called by muse, mutect2, varscan2
- C11orf1 | c.344-1G>T p.X115_splice | Splice Site (SNP) | VAF 9/50 reads (18%) | catalogued as rs145116726, COSV99499970; called by muse, mutect2, varscan2
- C8orf76 | c.851C>T p.S284L | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs374975138, COSV99414859; called by mutect2, varscan2
- CCDC70 | c.58G>T p.A20S | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as COSV54430525, COSV99665370; called by muse, mutect2, varscan2
- CD47 | c.619G>T p.A207S | Missense Mutation (SNP) | VAF 23/121 reads (19%) | SIFT tolerated (0.53); PolyPhen benign (0.166); catalogued as rs1308525788, COSV100790124; called by muse, mutect2, varscan2
- CGREF1 | c.103C>G p.Q35E | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT tolerated (0.29); PolyPhen benign (0.039); catalogued as COSV99565196; called by mutect2, varscan2
- CLIP1 | c.4199C>T p.S1400L (on ENST00000620786 / NM_001247997.1; = p.S1389L on NM_002956.2) | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as rs965447390, COSV100211850; called by mutect2, varscan2
- CNBD2 | c.273C>G p.I91M | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV100839009, COSV100839113; called by muse, mutect2, varscan2
- CNTN3 | c.1990G>A p.E664K | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.069); catalogued as rs1350870526, COSV55173355; called by muse, mutect2, varscan2
- COL16A1 | c.2155G>A p.E719K | Missense Mutation (SNP) | VAF 10/110 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.024); catalogued as COSV99594644; called by muse, mutect2
- COP1 | c.1162C>G p.Q388E | Missense Mutation (SNP) | VAF 20/129 reads (16%) | SIFT tolerated (1); PolyPhen possibly damaging (0.585); catalogued as rs1474592774, COSV100443400; called by muse, mutect2, varscan2
- CSMD3 | c.5231del p.G1744Efs*49 (on ENST00000297405 / NM_001363185.1; = p.G1640Efs*49 on NM_052900.3) | Frame Shift Del (DEL) | VAF 14/98 reads (14%) | catalogued as COSV52146370, COSV99822288; called by mutect2, pindel, varscan2
- CTSZ | c.785C>T p.S262L | Missense Mutation (SNP) | VAF 9/122 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99413432; called by muse, mutect2
- CXCL12 | c.122G>A p.R41K | Missense Mutation (SNP) | VAF 17/144 reads (12%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs1348700155, COSV100638951; called by muse, mutect2, varscan2
- DCBLD1 | c.1108C>T p.Q370* | Nonsense Mutation (SNP) | VAF 15/65 reads (23%) | catalogued as rs1186229621, COSV99757699; called by muse, mutect2, varscan2
- DCLRE1A | c.233C>G p.S78C | Missense Mutation (SNP) | VAF 18/232 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.72); catalogued as COSV100800387; called by muse, mutect2
- DGCR8 | c.1596C>G p.F532L | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.743); catalogued as COSV100707998, COSV61226317; called by mutect2, varscan2
- DHRS7 | c.973-1G>A p.X325_splice | Splice Site (SNP) | VAF 16/164 reads (10%) | catalogued as COSV99381626; called by muse, mutect2
- DIO2 | c.544G>T p.V182L | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.484); catalogued as COSV101375894; called by muse, mutect2, varscan2
- DNAH5 | c.3625G>A p.E1209K | Missense Mutation (SNP) | VAF 10/104 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.701); catalogued as COSV54263582; called by muse, mutect2
- EMC4 | c.518G>C p.R173T | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV50784678, COSV99272275; called by mutect2, varscan2
- EPN1 | c.133G>T p.D45Y | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV99321987; called by mutect2, varscan2
- EPS8L1 | c.502G>A p.A168T (on ENST00000201647 / NM_133180.3; = p.A41T on NM_017729.3) | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.528); catalogued as rs763596957, COSV99136444; called by muse, mutect2, varscan2
- ERICH3 | c.3334G>A p.E1112K | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.762); catalogued as rs757852992, COSV100444589; called by mutect2, varscan2
- EXO1 | c.1144G>T p.G382C | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.305); catalogued as COSV100799581; called by muse, mutect2, varscan2
- EXOSC10 | c.1343A>G p.Y448C | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100442606; called by muse, mutect2, varscan2
- F5 | c.3835G>A p.D1279N | Missense Mutation (SNP) | VAF 16/255 reads (6%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.08); catalogued as COSV100889130; called by muse, mutect2
- FAM47B | c.1842G>T p.K614N | Missense Mutation (SNP) | VAF 22/80 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.021); catalogued as COSV100264378; called by muse, mutect2, varscan2
- FARP2 | c.1175A>G p.E392G | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.086); catalogued as rs746551418, COSV99884787; called by mutect2, varscan2
- FMO1 | c.224C>A p.P75Q | Missense Mutation (SNP) | VAF 9/83 reads (11%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as COSV100707803; called by muse, mutect2
- FRYL | c.4070G>T p.G1357V | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99977116; called by mutect2, varscan2
- FRYL | c.4069G>T p.G1357* | Nonsense Mutation (SNP) | VAF 9/88 reads (10%) | catalogued as COSV51952221, COSV99977118; called by muse, mutect2, varscan2
- GAS8 | c.1235C>G p.S412W | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs548463078, COSV99244020; called by mutect2, varscan2
- GINS4 | c.568G>A p.E190K | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.176); catalogued as rs781762102, COSV99394563; called by mutect2, varscan2
- GLIPR1L2 | c.348T>G p.I116M | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as COSV100248628; called by muse, mutect2, varscan2
- GPATCH8 | c.556G>A p.E186K | Missense Mutation (SNP) | VAF 8/104 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.028); catalogued as COSV100132693; called by muse, mutect2
- GPR15 | c.991G>A p.E331K | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.054); catalogued as COSV99423784; called by muse, mutect2, varscan2
- GPR75 | c.46C>T p.L16F | Missense Mutation (SNP) | VAF 22/100 reads (22%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.055); catalogued as rs748159475, COSV100766142; called by muse, mutect2, varscan2
- GRIN3B | c.1607C>G p.S536C | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99312608; called by mutect2, varscan2
- IDI2 | c.376G>C p.E126Q | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.61); catalogued as COSV52988831; called by muse, mutect2, varscan2
- IGHMBP2 | c.873G>C p.Q291H | Missense Mutation (SNP) | VAF 12/100 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.726); catalogued as rs748408625, COSV99662146; called by mutect2, varscan2
- IL18RAP | c.982C>G p.Q328E | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT tolerated (0.77); PolyPhen benign (0.033); catalogued as COSV99962093; called by muse, mutect2
- ILDR2 | c.841C>A p.P281T | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.895); catalogued as COSV99613047, COSV99613986; called by muse, mutect2, varscan2
- INMT | c.520G>C p.D174H | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.9); catalogued as COSV99185025; called by muse, mutect2
- IRF2BPL | c.92C>G p.S31W | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.851); catalogued as rs1425872953, COSV99468190; called by muse, mutect2, varscan2
- JPH1 | c.1715G>T p.G572V | Missense Mutation (SNP) | VAF 21/109 reads (19%) | SIFT tolerated (0.61); PolyPhen benign (0.021); catalogued as COSV100646640; called by muse, mutect2, varscan2
- KANK1 | c.2328G>A p.M776I | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.02); catalogued as COSV100619889; called by mutect2, varscan2
- KIAA0586 | c.3626C>G p.S1209* (on ENST00000619416 / NM_001244190.2; = p.S1148* on NM_014749.5) | Nonsense Mutation (SNP) | VAF 5/51 reads (10%) | catalogued as COSV99708281; called by muse, mutect2, varscan2
- KIF27 | c.202C>A p.L68I | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99927033; called by mutect2, varscan2
- KL | c.1132C>T p.Q378* | Nonsense Mutation (SNP) | VAF 18/184 reads (10%) | catalogued as COSV101199070; called by muse, mutect2
- KRT3 | c.1106G>T p.S369I | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100527114; called by mutect2, varscan2
- LCOR | c.302C>A p.S101Y | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV100603654; called by mutect2, varscan2
- LRP1B | c.11527G>A p.E3843K | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT tolerated (0.28); PolyPhen benign (0.081); catalogued as COSV101257741; called by muse, mutect2, varscan2
- LRRC37A3 | c.3397G>C p.D1133H | Missense Mutation (SNP) | VAF 16/197 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV58535039, COSV58536353; called by muse, mutect2
- LRRC7 | c.2317G>A p.D773N (on ENST00000651989 / NM_001370785.2; = p.D740N on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/119 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.851); catalogued as COSV99227474; called by muse, mutect2, varscan2
- MAGEC3 | c.696C>G p.F232L | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT tolerated (0.55); PolyPhen benign (0.168); catalogued as COSV100025537; called by muse, mutect2, varscan2
- MFF | c.427G>A p.E143K | Missense Mutation (SNP) | VAF 26/174 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.538); catalogued as COSV100449342; called by muse, mutect2, varscan2
- MGAT4C | c.1093G>C p.D365H | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.613); catalogued as COSV59837639; called by muse, mutect2
- MUC16 | c.9659T>A p.I3220N | Missense Mutation (SNP) | VAF 12/129 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.036); catalogued as COSV101200122; called by muse, mutect2
- MYH3 | c.3316C>G p.Q1106E | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.91); catalogued as COSV99878315; called by muse, mutect2, varscan2
- NAV2 | c.2230G>T p.A744S (on ENST00000396087 / NM_001244963.2; = p.A721S on NM_145117.5) | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated (0.46); PolyPhen benign (0.101); catalogued as COSV100586460; called by muse, mutect2, varscan2
- NIPBL | c.1849G>A p.E617K | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.003); catalogued as COSV99240920; called by muse, mutect2, varscan2
- NLN | c.799G>C p.A267P | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV101114320; called by muse, mutect2, varscan2
- NRK | c.3797C>T p.S1266L | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99687488, COSV99688076; called by muse, mutect2
- NTNG1 | c.829G>A p.D277N | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.999); catalogued as COSV53964876, COSV99637837; called by muse, mutect2, varscan2
- OAS2 | c.2039G>T p.W680L | Missense Mutation (SNP) | VAF 10/155 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60802391, COSV60804741; called by muse, mutect2
- OPRM1 | c.1105C>A p.R369S | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.158); catalogued as COSV100001511, COSV57674181; called by mutect2, varscan2
- OR10Z1 | c.170C>G p.T57S | Missense Mutation (SNP) | VAF 20/175 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.052); catalogued as COSV100779031; called by muse, mutect2, varscan2
- OR2T35 | c.618G>T p.M206I | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV100442295; called by mutect2, varscan2
- PATJ | c.5119G>T p.A1707S | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.942); catalogued as rs749949716, COSV100957214; called by mutect2, varscan2
- PCDHA6 | c.1615G>T p.D539Y | Missense Mutation (SNP) | VAF 13/106 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV100971530, COSV65348503; called by muse, mutect2, varscan2
- PDE3B | c.1086G>T p.M362I | Missense Mutation (SNP) | VAF 14/95 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.095); catalogued as COSV99962673; called by muse, mutect2, varscan2
- PDZRN3 | c.887G>A p.G296E | Missense Mutation (SNP) | VAF 11/110 reads (10%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.666); catalogued as COSV99730088; called by muse, mutect2, varscan2
- PER3 | c.787G>T p.E263* | Nonsense Mutation (SNP) | VAF 6/45 reads (13%) | catalogued as COSV100728371, COSV62706829; called by muse, mutect2, varscan2
- PHF14 | c.1793C>T p.S598L | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.271); catalogued as COSV101301815; called by muse, mutect2, varscan2
- PHF3 | c.449C>G p.S150* | Nonsense Mutation (SNP) | VAF 13/163 reads (8%) | catalogued as COSV100012794; called by muse, mutect2
- PLD5 | c.973G>C p.D325H (on ENST00000442594; = p.D263H on NM_001195811.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100140721, COSV59173237; called by muse, mutect2, varscan2
- PNRC1 | c.175C>G p.H59D | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.215); catalogued as COSV100259933; called by mutect2, varscan2
- PPP1CC | c.662G>A p.R221K | Missense Mutation (SNP) | VAF 14/103 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV100534886; called by muse, mutect2, varscan2
- PPP1R13B | c.55G>A p.E19K | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.488); catalogued as COSV99159534; called by muse, mutect2, varscan2
- PRKDC | c.2632G>T p.E878* | Nonsense Mutation (SNP) | VAF 7/32 reads (22%) | catalogued as rs1319344777, COSV100041008; called by muse, mutect2, varscan2
- PRPF40B | c.2230G>A p.E744K (on ENST00000380281; = p.E731K on NM_012272.3) | Missense Mutation (SNP) | VAF 13/104 reads (13%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.034); catalogued as COSV99526426; called by muse, mutect2, varscan2
- PTPRH | c.304G>C p.E102Q | Missense Mutation (SNP) | VAF 20/192 reads (10%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.652); catalogued as COSV54749143, COSV99671088; called by mutect2, varscan2
- RBL2 | c.1093C>T p.L365F | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV100043423, COSV100043717; called by mutect2, varscan2
- RCN2 | c.361G>A p.E121K | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100312789; called by muse, mutect2, varscan2
- RELN | c.2466-1G>T p.X822_splice | Splice Site (SNP) | VAF 4/30 reads (13%) | catalogued as rs1442404996, COSV100633950, COSV58999315; called by mutect2, varscan2
- RFC4 | c.974C>G p.S325C | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.114); catalogued as COSV99961243, COSV99961450; called by muse, mutect2
- RGS22 | c.862C>T p.Q288* | Nonsense Mutation (SNP) | VAF 9/103 reads (9%) | catalogued as rs932703758, COSV100693330, COSV62665175; called by muse, mutect2
- SASH3 | c.592-1G>A p.X198_splice | Splice Site (SNP) | VAF 7/54 reads (13%) | catalogued as COSV100795240; called by muse, mutect2, varscan2
- SCAMP2 | c.785C>G p.S262* | Nonsense Mutation (SNP) | VAF 17/135 reads (13%) | catalogued as COSV51510435; called by muse, mutect2, varscan2
- SEC23A | c.1519C>G p.Q507E | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT tolerated (0.61); PolyPhen benign (0.028); catalogued as COSV100305551; called by muse, mutect2, varscan2
- SERPINA9 | c.953T>A p.L318Q | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100098452; called by mutect2, varscan2
- SETDB2 | c.395G>C p.R132T | Missense Mutation (SNP) | VAF 13/144 reads (9%) | SIFT tolerated (0.17); PolyPhen benign (0.108); catalogued as rs1273692027, COSV99320818; called by muse, mutect2
- SETX | c.3124G>C p.E1042Q | Missense Mutation (SNP) | VAF 12/118 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.08); catalogued as COSV99810002; called by muse, varscan2
- SLC35G2 | c.560C>G p.S187* | Nonsense Mutation (SNP) | VAF 13/104 reads (13%) | catalogued as COSV101262040; called by muse, mutect2, varscan2
- SNX13 | c.531G>C p.Q177H | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.537); catalogued as rs1258365598, COSV101285116; called by muse, mutect2
- SOX6 | c.956G>A p.G319E | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100322364; called by mutect2, varscan2
- SPINDOC | c.502G>A p.A168T | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs759066744, COSV99588692; called by muse, mutect2, varscan2
- SS18L1 | c.366G>C p.Q122H | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.916); catalogued as COSV100064985; called by muse, mutect2, varscan2
- STAT1 | c.340A>G p.K114E | Missense Mutation (SNP) | VAF 15/93 reads (16%) | SIFT tolerated (0.41); PolyPhen benign (0.088); catalogued as COSV100738686; called by muse, mutect2, varscan2
- SVEP1 | c.3973C>A p.Q1325K | Missense Mutation (SNP) | VAF 15/92 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.093); catalogued as COSV100238209; called by muse, mutect2, varscan2
- SYNE1 | c.4592G>A p.R1531K (on ENST00000367255 / NM_182961.4; = p.R1538K on NM_033071.3) | Missense Mutation (SNP) | VAF 10/114 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.035); catalogued as COSV99567081; called by muse, mutect2
- SYNE2 | c.12149A>G p.N4050S | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT tolerated (0.24); PolyPhen benign (0.005); catalogued as COSV100647849; called by muse, mutect2, varscan2
- TDRD1 | c.2975G>C p.R992T | Missense Mutation (SNP) | VAF 7/78 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.426); catalogued as COSV99314641; called by muse, mutect2
- THBS1 | c.2886G>A p.M962I | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.756); catalogued as COSV99528007; called by muse, mutect2, varscan2
- TLR4 | c.2126A>G p.Y709C (on ENST00000355622 / NM_138554.5; = p.Y669C on NM_003266.4) | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs377719663, COSV100842777; called by mutect2, varscan2
- TMEM131L | c.2545C>G p.L849V | Missense Mutation (SNP) | VAF 12/100 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV99547584; called by muse, mutect2, varscan2
- TPP2 | c.1477G>A p.E493K | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.341); catalogued as COSV101060295; called by muse, mutect2, varscan2
- TRMT10A | c.53del p.K18Sfs*4 | Frame Shift Del (DEL) | VAF 9/76 reads (12%) | catalogued as rs747549755; called by mutect2, pindel, varscan2
- TRNT1 | c.445G>A p.E149K | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated (0.41); PolyPhen benign (0.205); catalogued as rs780260411, COSV99285757; called by mutect2, varscan2
- TTC17 | c.1522G>A p.E508K | Missense Mutation (SNP) | VAF 18/184 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99235429; called by muse, mutect2, varscan2
- UBAP2L | c.2951C>T p.S984F | Missense Mutation (SNP) | VAF 14/275 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV99671470; called by muse, mutect2
- UBE2E3 | c.337G>A p.D113N | Missense Mutation (SNP) | VAF 40/177 reads (23%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.487); catalogued as COSV101150421, COSV101150714; called by muse, mutect2, varscan2
- USP47 | c.4045C>T p.R1349C (on ENST00000399455 / NM_001372095.1; = p.R1261C on NM_017944.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.432); catalogued as rs371170010; called by mutect2, varscan2
- USP9Y | c.646C>T p.R216* | Nonsense Mutation (SNP) | VAF 8/43 reads (19%) | catalogued as rs888918343, COSV100168365; called by muse, mutect2, varscan2
- VPS54 | c.2203G>C p.E735Q | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.168); catalogued as COSV55444398, COSV99708221; called by muse, mutect2, varscan2
- YARS1 | c.75G>T p.E25D | Missense Mutation (SNP) | VAF 37/322 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100993438; called by muse, mutect2, varscan2
- ZFP69B | c.1211G>A p.R404K | Missense Mutation (SNP) | VAF 7/70 reads (10%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.869); catalogued as COSV100848268; called by muse, mutect2, varscan2
- ZNF202 | c.38G>T p.W13L | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.968); catalogued as COSV100279064; called by muse, mutect2, varscan2
- ZNF221 | c.1402C>T p.H468Y | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52111145; called by muse, mutect2, varscan2
- ZNF365 | c.230C>G p.S77* | Nonsense Mutation (SNP) | VAF 7/40 reads (18%) | catalogued as COSV67926232; called by mutect2, varscan2
- ZNF507 | c.2403G>C p.L801F | Missense Mutation (SNP) | VAF 20/148 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100321884; called by muse, mutect2, varscan2
- ZNF7 | c.932G>A p.C311Y | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs773588606, COSV100295911; called by mutect2, varscan2
- ZNF766 | c.63G>C p.E21D | Missense Mutation (SNP) | VAF 24/256 reads (9%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); catalogued as COSV100765362; called by muse, mutect2, varscan2
- ZNRF4 | c.646G>A p.E216K | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as rs541728675, COSV99706564; called by mutect2, varscan2
- LILRB3 | c.141C>G p.I47M | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.104); called by muse, mutect2, varscan2
- OR4N2 | c.215_216del p.S72Lfs*49 | Frame Shift Del (DEL) | VAF 24/196 reads (12%) | called by mutect2, varscan2
- RAB3GAP2 | c.4142_4161del p.L1381Hfs*14 | Frame Shift Del (DEL) | VAF 12/94 reads (13%) | called by mutect2, pindel
- ACO2 | c.1455G>A p.E485= | Silent (SNP) | VAF 6/53 reads (11%) | catalogued as rs1237483884, COSV99347476; called by muse, mutect2, varscan2
- ACTR3B | c.1047C>T p.L349= | Silent (SNP) | VAF 5/44 reads (11%) | catalogued as rs146208789; called by mutect2, varscan2
- ALDOA | c.813G>C p.L271= (on ENST00000642816 / NM_001243177.4; = p.L217= on NM_184041.5) | Silent (SNP) | VAF 10/54 reads (19%) | catalogued as rs772297021, COSV100582108; called by mutect2, varscan2
- AQR | c.3480G>T p.V1160= | Silent (SNP) | VAF 7/39 reads (18%) | catalogued as COSV99334067; called by muse, mutect2, varscan2
- BAG6 | c.3252C>T p.L1084= (on ENST00000676571; = p.L1037= on NM_080702.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 6/36 reads (17%) | catalogued as COSV99277161; called by mutect2, varscan2
- BCAN | c.2184A>C p.T728= | Silent (SNP) | VAF 7/42 reads (17%) | catalogued as COSV100228174; called by muse, mutect2, varscan2
- BPTF | c.5103C>T p.V1701= | Silent (SNP) | VAF 14/82 reads (17%) | catalogued as COSV100075121; called by muse, mutect2, varscan2
- CBS | c.414C>T p.P138= | Silent (SNP) | VAF 4/18 reads (22%) | catalogued as rs201860288, COSV100657951; called by mutect2, varscan2
- CCNB3 | c.3153C>G p.P1051= | Silent (SNP) | VAF 9/46 reads (20%) | catalogued as COSV99328687, COSV99329215; called by muse, mutect2, varscan2
- CD180 | c.414C>A p.S138= | Silent (SNP) | VAF 14/146 reads (10%) | catalogued as COSV99842275; called by muse, mutect2
- CD4 | c.228G>A p.L76= | Silent (SNP) | VAF 17/159 reads (11%) | catalogued as COSV50596877; called by muse, mutect2, varscan2
- CHD3 | c.1251A>G p.K417= | Silent (SNP) | VAF 11/73 reads (15%) | catalogued as COSV100391284, COSV57880318; called by muse, mutect2, varscan2
- CHRNA2 | c.783C>T p.I261= | Silent (SNP) | VAF 9/37 reads (24%) | catalogued as COSV99532282; called by muse, mutect2, varscan2
- CHST9 | c.1146G>A p.Q382= | Silent (SNP) | VAF 13/98 reads (13%) | catalogued as COSV99410259; called by muse, mutect2, varscan2
- COL6A3 | c.2116C>T p.L706= | Silent (SNP) | VAF 4/34 reads (12%) | catalogued as COSV99798800; called by mutect2, varscan2
- DCLRE1A | c.2403C>T p.L801= | Silent (SNP) | VAF 6/34 reads (18%) | catalogued as COSV100800385; called by mutect2, varscan2
- ETV3 | c.21C>T p.I7= | Silent (SNP) | VAF 17/233 reads (7%) | catalogued as rs1007124749, COSV100461084; called by muse, mutect2
- FOXL2 | c.258G>A p.A86= | Silent (SNP) | VAF 14/160 reads (9%) | catalogued as rs1487527950, COSV100374601; called by muse, mutect2
- GAS2L2 | c.2265G>A p.L755= | Silent (SNP) | VAF 11/86 reads (13%) | called by muse, mutect2, varscan2
- HERC2 | c.2007C>T p.S669= | Silent (SNP) | VAF 13/85 reads (15%) | catalogued as COSV99874357; called by muse, mutect2, varscan2
- HIVEP2 | c.5997G>A p.Q1999= | Silent (SNP) | VAF 17/138 reads (12%) | catalogued as COSV99173767; called by muse, mutect2, varscan2
- INTS3 | c.3128G>A p.*1043= | Silent (SNP) | VAF 8/84 reads (10%) | catalogued as COSV99669970; called by mutect2, varscan2
- KCNH7 | c.2748C>A p.T916= | Silent (SNP) | VAF 7/78 reads (9%) | catalogued as COSV100148258; called by muse, mutect2
- KIF20A | c.1119C>G p.L373= | Silent (SNP) | VAF 6/58 reads (10%) | catalogued as COSV99137086; called by mutect2, varscan2
- KIF4B | c.822C>T p.I274= | Silent (SNP) | VAF 7/75 reads (9%) | catalogued as COSV101469297; called by mutect2, varscan2
- MDC1 | c.345G>C p.L115= | Silent (SNP) | VAF 5/27 reads (19%) | catalogued as COSV100902855, COSV64526555; called by muse, mutect2, varscan2
- METAP1D | c.57C>T p.F19= | Silent (SNP) | VAF 15/147 reads (10%) | catalogued as rs764314956, COSV59932073; called by mutect2, varscan2
- NSUN3 | c.798G>A p.T266= | Silent (SNP) | VAF 4/30 reads (13%) | catalogued as rs757041028, COSV100113313; called by mutect2, varscan2
- NTRK2 | c.1119G>A p.Q373= | Silent (SNP) | VAF 6/45 reads (13%) | catalogued as COSV99455767; called by muse, mutect2, varscan2
- PCDHA5 | c.2076G>T p.L692= | Silent (SNP) | VAF 13/67 reads (19%) | catalogued as rs1554129633, COSV100972342; called by muse, mutect2, varscan2
- PDE3A | c.825G>A p.L275= | Silent (SNP) | VAF 9/47 reads (19%) | catalogued as rs750288734, COSV62967221; called by mutect2, varscan2
- PHF21A | c.1278G>A p.R426= (on ENST00000418153 / NM_001101802.3; = p.R427= on NM_016621.5 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 10/141 reads (7%) | catalogued as rs988086483, COSV99138634; called by muse, mutect2
- PPIP5K1 | c.3582C>T p.F1194= (on ENST00000396923; = p.F1169= on NM_014659.5 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 11/58 reads (19%) | catalogued as COSV100288719; called by muse, mutect2, varscan2
- PRDM15 | c.1215G>A p.Q405= | Silent (SNP) | VAF 11/103 reads (11%) | catalogued as COSV99520238; called by muse, mutect2
- RUNX1T1 | c.12C>G p.V4= | Silent (SNP) | VAF 12/106 reads (11%) | catalogued as COSV56146531, COSV56155055, COSV99752575; called by muse, mutect2, varscan2
- SAMD12 | c.333G>T p.L111= | Silent (SNP) | VAF 15/90 reads (17%) | catalogued as COSV100126179, COSV59053721; called by muse, mutect2, varscan2
- SEMA3F | c.831C>T p.F277= | Silent (SNP) | VAF 6/36 reads (17%) | catalogued as COSV99137560; called by mutect2, varscan2
- SERPINF2 | c.1380G>A p.L460= | Silent (SNP) | VAF 14/83 reads (17%) | catalogued as COSV60665661; called by muse, mutect2, varscan2
- SIGLEC1 | c.2235C>T p.F745= | Silent (SNP) | VAF 5/30 reads (17%) | catalogued as COSV52466462; called by mutect2, varscan2
- SLC12A5 | c.1629C>A p.P543= (on ENST00000454036 / NM_001134771.2; = p.P520= on NM_020708.5) | Silent (SNP) | VAF 5/35 reads (14%) | catalogued as rs1346740381, COSV99716204; called by muse, mutect2, varscan2
- SLIT3 | c.1605C>T p.T535= | Silent (SNP) | VAF 7/38 reads (18%) | catalogued as rs1033096222, COSV60631830; called by muse, mutect2, varscan2
- SSBP4 | c.1157G>A p.*386= | Silent (SNP) | VAF 5/49 reads (10%) | catalogued as COSV99526132; called by mutect2, varscan2
- STX11 | c.684C>T p.F228= | Silent (SNP) | VAF 6/37 reads (16%) | catalogued as rs1206741163, COSV100845497; called by muse, mutect2, varscan2
- TAS2R5 | c.6G>A p.L2= | Silent (SNP) | VAF 5/44 reads (11%) | catalogued as COSV99924807, COSV99924853; called by mutect2, varscan2
- WDR11 | c.3570C>T p.L1190= | Silent (SNP) | VAF 10/98 reads (10%) | catalogued as rs745645916, COSV99676632; called by mutect2, varscan2
- WDR90 | c.264C>G p.L88= | Silent (SNP) | VAF 14/320 reads (4%) | catalogued as COSV99553553; called by muse, mutect2
- ZBBX | c.739C>T p.L247= | Silent (SNP) | VAF 15/156 reads (10%) | catalogued as rs1220015618, COSV100284205, COSV56792438, COSV56800194; called by muse, mutect2, varscan2
- ZNF343 | c.256C>T p.L86= | Silent (SNP) | VAF 12/110 reads (11%) | catalogued as rs1422337145, COSV99601453; called by muse, mutect2, varscan2
- ZNF493 | c.270C>T p.A90= | Silent (SNP) | VAF 18/117 reads (15%) | catalogued as COSV100828729; called by muse, mutect2, varscan2
- ZNF574 | c.1512C>T p.F504= | Silent (SNP) | VAF 25/204 reads (12%) | catalogued as COSV99726196; called by muse, mutect2, varscan2
- ANKRD20A5P | n.240G>A | RNA (SNP) | VAF 15/236 reads (6%) | called by muse, mutect2
